Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70G, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70G-01B (Primary Tumor).

[page 1 of 3]
Surgical Pathology

Final Results

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS:

1. Adrenal gland, left, adrenalectomy: Pheochromocytoma. Adjacent adrenal cortex shows thickening suggestive of hyperplasia. See Note.
2. Thyroid, left lobe, hemithyroidectomy: Colloid nodular disease.
3. Thyroid, right lobe, hemithyroidectomy: Colloid nodular disease.
4. Thyroid, right lobe, inferior nodule, biopsy: Benign reactive lymph node, no tumor seen.
5. Thymus, right, excision: Unremarkable thymic tissue.
6. Thymus, left, excision: Unremarkable thymic tissue.

NOTE: Immunostaining shows the lesional cells are positive for chromogranin and synaptophysin. S100 stains sustentacular cells.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief
Clinical History: L
adrenal nodule consistent w/ pheochromocytoma, large multinodular goiters, hypercalcemia Specimen Taken For Protocol: 01 - Yes

PROCEDURE: Pre-Operative Diagnosis: left adrenal pheochromocytoma, goiters,
hyperparathyroidism Post-Operative Diagnosis: same Operative
Findings: large goiters

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, LEFT
2. THYROID, LEFT LOBE
3. THYROID, RIGHT LOBE
4. THYROID, RIGHT LOBE, Inferior Nodule
5. THYMUS, Right
6. THYMUS, Left

GROSS DESCRIPTION:

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 2 of 3]
Surgical Pathology [1]

1. Received fresh in a container labeled with the patient's name, medical record number, and Left adrenal is a left adrenal gland with associated fat measuring 8 x 3 x 2.2 cm and weighing 15.6 grams. The external surface is inked black. Within the mid gland is pink fleshy medullary nodule measuring 1.9 x 1.5 x 1.5 cm rimmed by up to 0.2 cm thick yellow to orange cortex. The remaining cortex is focally thickened up to 0. cm and mottled yellow, orange and red. Gross photographs are taken. Approximately 50% of the nodule and approximately 1 x 1 x 0.4 cm of normal-appearing gland are procured for at laboratory by .

The remainder of the specimen is placed into formalin and submitted to Pathology for permanent. The specimen is received in Pathology and matches the above description. The specimen is unoriented. It has been inked black on the external surface and has been serially sectioned throughout. There is a nodular area in the mid adrenal. The specimen is serially sectioned throughout and submitted in consecutive white cassettes labeled with cassettes and corresponding to the nodule from which procurement took place. The specimens are all in consecutive, except for the specimens in and which were received fragmented.

2. "Thyroid left". It consists of a left thyroidectomy specimen measuring 10 x 6.5 x 5.5 cm and weighing 158 grams. It is oriented with a stitch marking the left superior and another stitch which is longer and believed to represent lateral. The specimen appears to contain at least 3 distinct nodules, the largest measuring 7 cm in greatest dimension, the second measuring 5 cm in greatest diameter and a third measuring 4.2 cm in greatest dimension diameter. The external surface is inked black. The specimen is sectioned revealing a variegated brown to tan normal-appearing thyroid parenchyma with areas of yellow to tan nodularity. The largest individual nodule measures 5 cm in greatest dimension. Representative sections are submitted in white cassettes labeled with corresponding to more superior region and corresponding to more inferior regions.

3. "Right thyroid". It consists of a hemithyroidectomy specimen measuring 8.5 x 3.5 x 3.5 cm and weighing 61 grams. The projection from lateral edge of the specimen is possibly a pyramidal lobe measuring 3 x 2 x 1 cm. The external surface of the specimen is inked black. The specimen is serially sectioned revealing areas of normal-appearing brown thyroid parenchyma and areas of yellow to tan nodularity. The largest nodule measures approximately 2.0 cm in greatest dimension. The specimen is serially sectioned and submitted in white cassettes labeled with being most inferior, being superior, and a representative section of the pyramidal lobe.

4. "Right inferior node." It consists of a tan to gray soft tissue fragment measuring 0.2 x 0.2 x 0.2 cm which is wrapped in a tea bag and entirely submitted in a white cassette labeled

5. "Right thymus". It consists of a yellow to tan soft tissue fragment measuring 7.5 x 1.0 x 0.7 cm. It is serially sectioned revealing a homogeneous yellow tan cut surface with occasional areas of hemorrhage.

[page 3 of 3]
Surgical Pathology

Final Results

Representative sections are taken and placed into white cassettes labeled

6. "Left thymus". It consists of a yellow to tan fibroadipose tissue soft tissue fragment measuring 5.2 x 2.2 x 0.8 cm. It is serially sectioned and revealing a homogeneous yellow to tan cut surface. It is serially sectioned and representative sections are submitted in white cassettes labeled

Gross Description dictated by

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

hw 7/25/13

Confidential: Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By: I

Do not file in Medical Record

Source: NCI Genomic Data Commons file 068e3afe-9ef9-414f-9e5a-f90337f6fe96 (TCGA-QR-A70G.5279076B-519C-46AE-9A9F-8766C501F35F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).